Somatic mutation profile of tumor specimen TCGA-AB-2834-03B (aliquot TCGA-AB-2834-03B-01W-0728-08) from TCGA case TCGA-AB-2834, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.6 years (12,266 days).
Specimen TCGA-AB-2834-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eefe106-a309-40e1-839d-aa8521496aa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2834-11B (Solid Tissue Normal), aliquot TCGA-AB-2834-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89492b83-d19a-4183-8cad-cca3e1ae83e3

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LIMK1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs781956388, COSV60281124; called by muse, mutect2
- TUBD1 | c.935-2_935del p.X312_splice | Splice Site (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel*
